Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8436, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8436-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

*****CORRECTED REPORT*****

Revised report to change and clarify staging in synoptic report; the synoptic should read:

Macroscopic extent of tumor: Tumor limited to kidney.

Venous invasion: Indeterminate (see comment):

Comment: There are foci within the renal sinus suspicious for vascular invasion. has reviewed slides C-I and Dr. has reviewed slides C-I and P-S.

Right kidney, nephrectomy:

Oncocytic neoplasm with features most consistent with chromophobe renal cell carcinoma, see synoptic report.

Kidney: Nephrectomy, partial or radical Synopsis

MACROSCOPIC

Specimen Type: Right radical nephrectomy.

[page 2 of 3]
[REDACTED]

Focality: Unifocal.

Tumor Size

Greatest dimension: 13.8 cm.

Macroscopic extent of tumor: Tumor extends into renal sinus vein.

MICROSCOPIC

Histologic Type:

Chromophobe renal cell carcinoma.

EXTENT OF INVASION

Primary Tumor: pT2: Tumor more than 7 cm in greatest dimension, limited to the kidney.

Regional Lymph Nodes: pNX: Cannot be assessed.

Distant metastasis: pMX: Cannot be assessed.

Margins:

Margins uninvolved by invasive carcinoma.

Adrenal gland: Not present.

Venous invasion: Present.

Additional Pathologic Findings: None identified.

ADDENDUM:

Tumor stains positively for PAX-2, C-kit and CK7

[REDACTED]

Clinical: Right kidney mass.

Gross: The specimen is received fresh labeled with the patient's name [REDACTED] and the medical record number and "right kidney." It consists of a nephrectomy specimen with attached perinephric adipose tissue that measures 25.0 x 15.0 x 7.5 cm overall. A segment of ureter is present that measures 1.0 cm in length. An adrenal gland is not present. The kidney is bivalved. A mass is present that measures 13.8 x 7.0 cm. The mass has replaced the majority of the kidney. The cut surface of the mass has areas that are both solid and cystic, yellow, brown and hemorrhagic with extensive necrosis present. Tumor invasion into the perinephric adipose tissue is not identified. Invasion of the renal vein is not grossly

[REDACTED]

[page 3 of 3]
[REDACTED]

identified. The tumor does not appear to be at the linked margin. No other masses are identified in the renal parenchyma. No lymph nodes are grossly evident. The mucosa of the ureter and pelvis are unremarkable. The specimen is represented as follows; A = ureter margin, B = vascular margins, C-I = mass, J = normal kidney, K-O = hilar fat (possible lymph nodes), P = mass from region of pelvis, Q-S = mass in relation to perinephric fat.

[REDACTED]

Source: NCI Genomic Data Commons file 77810938-ac9f-4de3-8a84-7065d9fc7eb3 (TCGA-KN-8436.FAE13077-3AB2-448E-A45C-66C090C32C92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).